Somatic mutation profile of tumor specimen TARGET-30-PATIYD-09A (aliquot TARGET-30-PATIYD-09A-01D) from TARGET case TARGET-30-PATIYD, project TARGET-NBL (Neuroblastoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Neuroblastoma, NOS; Tissue or organ of origin: Abdomen, NOS; Age at diagnosis: 1.5 years (538 days).
Specimen TARGET-30-PATIYD-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ce4b2287-6f7f-4a25-a829-f7de570c251b.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-30-PATIYD-10A (Blood Derived Normal), aliquot TARGET-30-PATIYD-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e3987729-74f7-4e79-98fc-04c0301571c4

The open-access MAF lists 2 somatic variants for this specimen: 1 protein-altering or splice-affecting, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: 3'UTR 1, Missense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TAF1L | c.4399C>A p.H1467N | Missense Mutation (SNP) | VAF 76/254 reads (30%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.491); catalogued as COSV54267389, COSV54268489; called by muse, mutect2, varscan2
- FASTKD1 | c.*98G>T | 3'UTR (SNP) | VAF 12/56 reads (21%) | called by muse, mutect2
